Gene-level copy-number profile of tumor specimen C3N-03782-01 from CPTAC case C3N-03782, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 50.8 years (18,540 days).
Specimen C3N-03782-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f1f8613-62b4-4325-8518-1781c9cddfea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03782-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/20f6f387-1b82-4e98-9860-669a5349cd6d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 758; copy number 2: 7,206; copy number 3: 31,467; copy number 4: 18,191; copy number 5: 466; copy number 7: 127; copy number 8: 6; copy number 10: 1; copy number 16: 52; copy number 17: 61; copy number 59: 21.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr5:180,967,189–181,007,384, 5 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr8:7,926,337–7,952,413, 2 genes (within-gene range 0–1): ZNF705B, DEFB108A.
- chr9:21,638,285–23,438,700, 23 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:61,581,813–61,666,386, 5 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:63,581,254–63,581,834, 1 gene: AL591438.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 268 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–57,837,046, 140 genes, copy number 8–59 (broad region; genes not listed).
- chr7:63,556,598–63,585,075, 2 genes, copy number 7–10: SLC29A4P2, TNRC18P2.
- chr9:39,734,670–40,153,147, 15 genes, copy number 7: RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr13:72,453,902–74,565,445, 33 genes, copy number 7: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr16:32,715,931–34,163,110, 78 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
